Gene-level copy-number profile of tumor specimen HCM-BROD-0118-C16-06A from HCMI case HCM-BROD-0118-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: GX; Age at diagnosis: 46.0 years (16,790 days).
Specimen HCM-BROD-0118-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f908939-eff7-464d-8c90-5fc4a6689bda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0118-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/557d21b6-99f6-4059-956d-514463e33b3c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 18; copy number 2: 5,098; copy number 3: 1,579; copy number 4: 41,267; copy number 5: 417; copy number 6: 7,994; copy number 7: 699; copy number 8: 866; copy number 9: 93; copy number 10: 8; copy number 11: 20; copy number 12: 66; copy number 13: 13; copy number 21: 34; copy number 25: 27; copy number 35: 6; copy number 56: 123; copy number 62: 56.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:177,442,519–177,681,381, 2 genes: AC078881.1, RNA5SP172.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 446 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:42,892,396–43,234,956, 3 genes, copy number 9: RN7SKP82, GRXCR1, AC111198.1.
- chr4:64,275,257–66,897,371, 28 genes, copy number 9–11: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, LINC02232, AC107058.1, EFL1P2, AC096754.1, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P.
- chr4:151,027,090–151,027,617, 1 gene, copy number 11: AK4P6.
- chr8:107,857,589–107,963,516, 1 gene, copy number 9 (within-gene range 6–9): AC025508.1.
- chr8:107,899,316–114,318,911, 50 genes, copy number 9: RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA, AC064802.1, AC025881.1.
- chr8:116,642,130–116,944,487, 6 genes, copy number 10: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr8:129,728,744–131,712,980, 25 genes, copy number 9: MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1.
- chr9:32,455,302–34,048,949, 66 genes, copy number 12 (broad region; genes not listed).
- chr17:13,494,032–14,421,472, 15 genes, copy number 10–13: HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2, AC022816.1.
- chr17:37,084,992–41,930,542, 246 genes, copy number 21–62 (broad region; genes not listed).
- chr18:79,787,121–79,951,657, 5 genes, copy number 11: AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
